Somatic mutation profile of tumor specimen TCGA-DD-A3A2-01A (aliquot TCGA-DD-A3A2-01A-11D-A20W-10) from TCGA case TCGA-DD-A3A2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 76.5 years (27,930 days).
Specimen TCGA-DD-A3A2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 163c13d1-7c9b-4c5d-b2f1-70373690a430.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A2-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A2-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8afe0c9-fbad-4705-a211-21834bb4bafa

The open-access MAF lists 80 somatic variants for this specimen: 62 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, RNA 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1A | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as rs1057520291, CM093342, CM971451, COSV57458707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV64101834; called by muse, mutect2, varscan2
- ADAM29 | c.62A>C p.Q21P | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV63659781; called by muse, mutect2, varscan2
- ALG1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52156135; called by muse, mutect2, varscan2
- ASB6 | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV52964309; called by muse, mutect2, varscan2
- BAZ1A | c.3831A>C p.K1277N | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV62408790; called by muse, mutect2
- CHRNA4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV64717277; called by muse, mutect2, varscan2
- CSRP3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | catalogued as COSV56388863; called by muse, mutect2
- CTC1 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs1209456215, COSV59851783; called by muse, mutect2, varscan2
- CUL4A | c.1282G>T p.E428* (on ENST00000375440 / NM_001008895.4; = p.E328* on NM_003589.3) | Nonsense Mutation (SNP) | VAF 88/215 reads (41%) | catalogued as COSV58370862; called by muse, mutect2, varscan2
- DIPK1B | c.944A>C p.D315A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV63037676; called by muse, mutect2, varscan2
- ELN | c.2026G>A p.G676R (on ENST00000320399 / NM_001278939.1; = p.G643R on NM_000501.4) | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV52706528; called by muse, mutect2
- ENOPH1 | c.626T>G p.F209C | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56730274; called by muse, mutect2, varscan2
- ESCO1 | c.1799C>A p.T600N | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV52517930; called by muse, mutect2, varscan2
- FOXJ2 | c.1721C>G p.T574S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); catalogued as COSV50817381; called by muse, mutect2, varscan2
- FURIN | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV51574426; called by muse, mutect2, varscan2
- GATC | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56663221; called by muse, mutect2
- GBP5 | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs752091819, COSV58591216, COSV58593543; called by muse, mutect2, varscan2
- GFM2 | c.1605G>C p.M535I | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57189430, COSV57190827; called by muse, mutect2, varscan2
- GLI3 | c.3641A>C p.Q1214P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV67884660; called by muse, mutect2, varscan2
- HNF1A | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as CM133564, COSV57458725, COSV57462046; called by muse, mutect2, varscan2
- HTR7 | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53282292; called by muse, mutect2, varscan2
- HTT | c.5356A>G p.I1786V | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1260457762, COSV61856819; called by muse, mutect2, varscan2
- ITFG2 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.165); catalogued as COSV57388983; called by muse, mutect2, varscan2
- ITGA9 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); catalogued as rs779583800, COSV53235100, COSV53239334; called by muse, mutect2, varscan2
- KALRN | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV53751649, COSV99565330; called by muse, mutect2
- KDM7A | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV50089993; called by muse, mutect2, varscan2
- KMT2E | c.2701A>G p.T901A | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV57568996; called by muse, mutect2, varscan2
- KPNB1 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV51594563; called by muse, mutect2
- LARGE1 | c.2123A>T p.H708L | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61657189; called by muse, mutect2, varscan2
- LUZP2 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs773564969, COSV61193831, COSV61196268; called by muse, mutect2, varscan2
- MICAL3 | c.4987C>G p.L1663V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); catalogued as COSV71588020; called by muse, mutect2, varscan2
- OR8G5 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV100422181, COSV100422652, COSV58379558; called by muse, mutect2, varscan2
- PCDH10 | c.2686A>C p.N896H | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV52086687; called by muse, mutect2, varscan2
- PCDHA5 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs782395290, COSV65348918; called by muse, mutect2, varscan2
- PLEKHS1 | c.400A>G p.T134A (on ENST00000369310 / NM_182601.1; = p.T140A on NM_024889.5) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63053870; called by muse, mutect2, varscan2
- PLTP | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV51940343; called by muse, mutect2, varscan2
- POLK | c.694+1G>C p.X232_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV54031405, COSV99606297; called by muse, mutect2, varscan2
- RALY | c.596C>T p.S199F (on ENST00000246194 / NM_016732.3; = p.S183F on NM_007367.4) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as COSV55779532; called by muse, mutect2, varscan2
- ROR1 | c.2762G>A p.G921E | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs899194498, COSV64283508; called by muse, mutect2, varscan2
- RPS6KA4 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV53700284; called by muse, mutect2, varscan2
- SETD1A | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52684623, COSV52690874; called by muse, mutect2, varscan2
- SH2B1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV59460252; called by muse, mutect2, varscan2
- TACR3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as CM119299, COSV59197428; called by muse, mutect2, varscan2
- TAF3 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778575614, COSV60202770; called by muse, mutect2, varscan2
- TAF5 | c.1535-1G>C p.X512_splice | Splice Site (SNP) | VAF 62/148 reads (42%) | catalogued as COSV60856162; called by muse, mutect2, varscan2
- TFEB | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs370711905; called by muse, mutect2, varscan2
- TRIM67 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370312974; called by muse, mutect2, varscan2
- TRIP4 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV56029349; called by muse, mutect2
- URB2 | c.4401A>C p.K1467N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50980991; called by muse, mutect2
- ZDHHC17 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs562629778, COSV58350025; called by muse, mutect2, varscan2
- ZFAND4 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60857485; called by muse, mutect2, varscan2
- ZNF142 | c.1645G>T p.D549Y (on ENST00000411696 / NM_001379660.1; = p.D349Y on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV68742850; called by muse, mutect2, varscan2
- ZNF521 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64121466; called by muse, mutect2, varscan2
- ZNF611 | c.1552G>C p.V518L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV60539350; called by muse, mutect2, varscan2
- CPAMD8 | c.723del p.L242Cfs*38 (on ENST00000651564; = p.L195Cfs*38 on NM_015692.5) | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by pindel, varscan2
- CWC25 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- FCHO2 | c.969delinsAA p.Y323* | Nonsense Mutation (INS) | VAF 15/81 reads (19%) | called by mutect2*, pindel
- FKBP15 | c.2164_2166del p.V722del | In Frame Del (DEL) | VAF 90/289 reads (31%) | called by mutect2, pindel, varscan2
- KMT2D | c.13252del p.E4418Nfs*14 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- SECISBP2L | c.2748_2749insCAACTTCCATTTGACACACCCCCA p.P916_I917insQLPFDTPP (on ENST00000559471 / NM_001193489.2; = p.P871_I872insQLPFDTPP on NM_014701.4) | In Frame Ins (INS) | VAF 50/160 reads (31%) | called by mutect2, pindel
- WASHC2A | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CACNA1H | c.1485G>A p.V495= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV61982589; called by muse, mutect2, varscan2
- CCR10 | c.1026C>T p.R342= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs751380970, COSV52847664; called by muse, mutect2, varscan2
- CPAMD8 | c.717C>T p.S239= (on ENST00000651564; = p.S192= on NM_015692.5) | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV52230599; called by muse, varscan2
- CTSE | c.552A>C p.A184= (on ENST00000360218; = p.A179= on NM_001910.4) | Silent (SNP) | VAF 101/261 reads (39%) | catalogued as COSV63059613; called by muse, mutect2, varscan2
- CYP2A6 | c.543C>G p.V181= | Silent (SNP) | VAF 123/318 reads (39%) | catalogued as COSV56533475; called by muse, mutect2, varscan2
- DNAH6 | c.1374T>C p.N458= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV52848091; called by muse, mutect2, varscan2
- HYAL3 | c.246C>T p.P82= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV56496538; called by muse, mutect2, varscan2
- IGHV3-49 | c.135A>T p.G45= | Silent (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- ITK | c.1729T>C p.L577= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs959899813, COSV70060203; called by muse, mutect2
- LCNL1 | c.99G>T p.L33= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as COSV56399214; called by muse, mutect2, varscan2
- MGAM | c.1002G>T p.A334= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as COSV101527373, COSV101527664, COSV72073467; called by muse, mutect2, varscan2
- NLRP10 | c.1350C>T p.N450= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs56052845, COSV60778459; called by muse, mutect2, varscan2
- POLA1 | c.1305G>T p.V435= | Silent (SNP) | VAF 173/410 reads (42%) | catalogued as COSV66883325; called by muse, mutect2, varscan2
- PRELID2 | c.495A>C p.R165= (on ENST00000334744 / NM_182960.4; = p.R124= on NM_138492.6) | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV58278109; called by muse, mutect2, varscan2
- TMC2 | c.1347C>T p.Y449= | Silent (SNP) | VAF 67/215 reads (31%) | catalogued as COSV62649361; called by muse, mutect2, varscan2
- TMEM219 | c.390C>T p.A130= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs1471443164, COSV54243322; called by muse, mutect2, varscan2
- VAMP1 | c.69C>T p.G23= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV56945716; called by muse, mutect2, varscan2
- DCHS2 | n.6759G>T | RNA (SNP) | VAF 26/72 reads (36%) | catalogued as COSV61767411, COSV61774393; called by muse, mutect2, varscan2
